Somatic mutation profile of tumor specimen ALCH-B3E4-TTP1-A (aliquot ALCH-B3E4-TTP1-A-2-0-D-A78R-36) from ALCHEMIST case ALCH-B3E4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.4 years (23,519 days).
Specimen ALCH-B3E4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fa0699a-4fb1-4f16-a8f7-e7e02107174f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3E4-NB1-A (Blood Derived Normal), aliquot ALCH-B3E4-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0494c2d-9539-4746-85f6-cdc240390453

The open-access MAF lists 181 somatic variants for this specimen: 114 protein-altering or splice-affecting, 42 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 42, Intron 12, Nonsense Mutation 6, RNA 5, 5'UTR 4, Splice Site 2, Frame Shift Del 2, 3'UTR 2, 5'Flank 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC100868.1 | c.1444G>T p.G482W | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1305605407, COSV99226747; called by muse, mutect2
- ADAM2 | c.772C>A p.L258I | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV55860152; called by muse, mutect2
- ADAMTS12 | c.2966C>T p.A989V | Missense Mutation (SNP) | VAF 22/606 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as rs866850332; called by muse, mutect2
- ATAD2B | c.3272C>G p.S1091* | Nonsense Mutation (SNP) | VAF 18/371 reads (5%) | catalogued as COSV99478367; called by muse, mutect2
- BTN1A1 | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542740353, COSV55068151; called by muse, mutect2, varscan2
- CALB1 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 48/580 reads (8%) | catalogued as COSV55369148; called by muse, mutect2
- CAPN6 | c.1780G>T p.G594W | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100136595; called by muse, mutect2, varscan2
- CHRNB3 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1450482545, COSV51494787; called by muse, mutect2
- CYP2A13 | c.1403C>G p.P468R | Missense Mutation (SNP) | VAF 25/489 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as rs1468949194; called by muse, mutect2
- DIAPH2 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as rs1334461463, COSV61298487; called by muse, mutect2
- ELP1 | c.2864C>G p.P955R | Missense Mutation (SNP) | VAF 37/390 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs758112773; called by muse, mutect2
- HEPACAM2 | c.1138G>A p.V380I (on ENST00000394468 / NM_001039372.4; = p.V368I on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV59060562; called by muse, mutect2, varscan2
- HMGCLL1 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51443280; called by muse, mutect2, varscan2
- HTR3A | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs747533474; called by muse, mutect2, varscan2
- INSRR | c.1978+1G>A p.X660_splice | Splice Site (SNP) | VAF 8/63 reads (13%) | catalogued as rs375517259; called by muse, mutect2, varscan2
- KRT27 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 54/495 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs762368035; called by muse, mutect2, varscan2
- LAMA1 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 133/609 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs139065838, COSV67541830; called by muse, mutect2, varscan2
- LRRC4B | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1312061741; called by muse, mutect2, varscan2
- MICALL1 | c.2477A>G p.Q826R | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs907841919; called by muse, varscan2
- MTCL1 | c.1655C>T p.P552L (on ENST00000306329 / NM_001378206.1; = p.P192L on NM_015210.4) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868261209; called by muse, mutect2
- NBPF26 | c.2688C>G p.D896E (on ENST00000620612; = p.D634E on NM_001351372.1) | Missense Mutation (SNP) | VAF 22/568 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.316); catalogued as rs1553272418; called by muse, mutect2
- NELFA | c.406A>T p.R136* (on ENST00000542778; = p.R125* on NM_005663.5) | Nonsense Mutation (SNP) | VAF 32/172 reads (19%) | catalogued as COSV100424701; called by muse, mutect2, varscan2
- OR8K3 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 50/342 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.17); catalogued as COSV57133105; called by muse, mutect2, varscan2
- PAK2 | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV59080143; called by muse, varscan2
- PRAME | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 30/172 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as COSV67161490; called by muse, mutect2, varscan2
- PTPN23 | c.3086C>T p.A1029V | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1180507159; called by muse, mutect2
- RARA | c.994A>G p.I332V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.747); catalogued as rs1303998335; called by muse, mutect2, varscan2
- REG3A | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs538408283, COSV100532830, COSV59409033; called by muse, mutect2, varscan2
- RNF111 | c.2582G>T p.R861L | Missense Mutation (SNP) | VAF 50/442 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.19); catalogued as COSV62085602; called by muse, mutect2, varscan2
- RPL3L | c.1170C>A p.G390= | Splice Region (SNP) | VAF 7/162 reads (4%) | catalogued as rs1384523980; called by muse, mutect2
- SEC31A | c.3496A>G p.I1166V (on ENST00000355196 / NM_001318120.1; = p.I1127V on NM_016211.4) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.977); catalogued as rs759539725; called by muse, mutect2, varscan2
- SHROOM2 | c.2864G>A p.R955Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs770300117; called by muse, mutect2, varscan2
- SI | c.2183G>T p.W728L | Missense Mutation (SNP) | VAF 104/931 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV52291260; called by muse, mutect2, varscan2
- SIGLEC1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as rs746344537, COSV52462125; called by muse, mutect2, varscan2
- SLC5A12 | c.1183A>G p.M395V | Missense Mutation (SNP) | VAF 50/586 reads (9%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.626); catalogued as COSV68449847; called by muse, mutect2
- TBXA2R | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781001993; called by muse, mutect2
- TFE3 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV59946972; called by muse, mutect2
- TP53 | c.262del p.A88Pfs*35 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | catalogued as COSV53134951; called by mutect2, pindel, varscan2
- TRPC7 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1391101274, COSV61459664; called by muse, mutect2
- TTN | c.40948A>G p.S13650G (on ENST00000591111; = p.S6226G on NM_003319.4) | Missense Mutation (SNP) | VAF 93/850 reads (11%) | PolyPhen benign (0.439); catalogued as COSV59864262, COSV59925441; called by muse, mutect2, varscan2
- USB1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs763524876; called by muse, mutect2, varscan2
- WNK1 | c.932+1G>T p.X311_splice | Splice Site (SNP) | VAF 42/620 reads (7%) | catalogued as COSV60041609; called by muse, mutect2
- ZNF528 | c.1579G>A p.G527S | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as rs967287935; called by muse, mutect2, varscan2
- ABCB7 | c.2098A>G p.I700V (on ENST00000373394 / NM_001271696.3; = p.I701V on NM_004299.6) | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ABCC3 | c.3982G>T p.G1328C | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AHNAK2 | c.6714G>T p.K2238N | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2
- AKR1B10 | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 16/421 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- BRD2 | c.1381G>C p.G461R | Missense Mutation (SNP) | VAF 20/500 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.031); called by muse, mutect2
- BTBD7 | c.1615A>G p.R539G | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- C12orf66 | c.660C>A p.H220Q | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- C8orf34 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated, low confidence (0.06); called by muse, mutect2
- CAPN6 | c.1779G>T p.L593F | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDO1 | c.547A>C p.S183R | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COQ9 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 79/658 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CPNE3 | c.373A>T p.K125* | Nonsense Mutation (SNP) | VAF 105/600 reads (18%) | called by muse, mutect2, varscan2
- DPP4 | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 42/698 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2
- ESR1 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- F5 | c.4903G>C p.G1635R | Missense Mutation (SNP) | VAF 44/426 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM184B | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- FAT2 | c.9442G>A p.V3148M | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FILIP1L | c.187C>A p.Q63K | Missense Mutation (SNP) | VAF 97/478 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABBR1 | c.2225C>G p.A742G | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- GALNT11 | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- HECTD4 | c.4325C>G p.S1442* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- HSD17B13 | c.875T>A p.V292E | Missense Mutation (SNP) | VAF 89/323 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- HTR1F | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2
- IDUA | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IKZF2 | c.1040T>G p.V347G | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2
- IL12A | c.541A>T p.M181L | Missense Mutation (SNP) | VAF 57/460 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- INPP4A | c.2633G>T p.W878L (on ENST00000074304 / NM_001134224.1; = p.W839L on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2
- IRX4 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ITPR3 | c.1645T>A p.Y549N | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- KDR | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 95/503 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- KPRP | c.1561C>A p.H521N | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.069); called by muse, mutect2
- LIPF | c.103A>C p.I35L | Missense Mutation (SNP) | VAF 13/275 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2
- LPCAT1 | c.928A>G p.T310A | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.218); called by muse, mutect2
- LRFN5 | c.1568A>T p.Q523L | Missense Mutation (SNP) | VAF 65/519 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by mutect2, varscan2
- LRRC8D | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEB10 | c.767A>G p.N256S | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2
- MYBBP1A | c.1353G>C p.W451C | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NELL2 | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 49/376 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NFYA | c.656C>A p.T219N | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.715); called by muse, mutect2
- NIPBL | c.4316C>G p.T1439S | Missense Mutation (SNP) | VAF 26/822 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.189); called by muse, mutect2
- NKX6-3 | c.145del p.A49Pfs*11 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- NR2E1 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- OR2T27 | c.653A>T p.Y218F | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAPPA2 | c.2104T>C p.W702R | Missense Mutation (SNP) | VAF 41/483 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PGBD5 | c.928T>C p.S310P (on ENST00000525115; = p.S379P on NM_001258311.2) | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.874); called by muse, mutect2
- PPP1R32 | c.523A>T p.M175L | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RAPGEF6 | c.4406A>T p.K1469M | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- RASL12 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- REG3G | c.406A>C p.N136H | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- RHBDL2 | c.472C>G p.R158G | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SCN7A | c.4744A>G p.T1582A | Missense Mutation (SNP) | VAF 16/423 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- SEC14L6 | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SKP2 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 34/913 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.071); called by muse, mutect2
- SLIT2 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2
- SMG1 | c.7904G>C p.R2635P | Missense Mutation (SNP) | VAF 81/526 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPTA1 | c.6959A>G p.E2320G | Missense Mutation (SNP) | VAF 22/841 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- SSBP1 | c.283A>T p.R95* | Nonsense Mutation (SNP) | VAF 18/383 reads (5%) | called by muse, mutect2
- STON1-GTF2A1L | c.3018G>C p.R1006S | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SYNE1 | c.16960A>G p.T5654A (on ENST00000367255 / NM_182961.4; = p.T5583A on NM_033071.3) | Missense Mutation (SNP) | VAF 54/597 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.376); called by muse, mutect2
- TNKS1BP1 | c.3191A>G p.Q1064R | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TNR | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TRAJ23 | c.3G>A p.*1= | Missense Mutation (SNP) | VAF 73/524 reads (14%) | called by muse, mutect2, varscan2
- TRIM15 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- TTC28 | c.6112A>G p.R2038G | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- UBQLN3 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UCN3 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- VAT1 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 73/404 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- WDR6 | c.1724T>G p.V575G | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- WDR93 | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFAT | c.2516T>C p.F839S | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- ZNF367 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ABCA13 | c.8199T>G p.S2733= | Silent (SNP) | VAF 24/276 reads (9%) | catalogued as COSV101447322; called by muse, mutect2
- ADCY2 | c.2340C>T p.T780= | Silent (SNP) | VAF 28/559 reads (5%) | called by muse, mutect2
- ADGRV1 | c.18633T>A p.P6211= | Silent (SNP) | VAF 33/295 reads (11%) | catalogued as COSV101315593; called by muse, mutect2, varscan2
- CCNI2 | c.117C>T p.L39= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- CHST1 | c.192C>T p.L64= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as rs200379237, COSV57324649; called by muse, mutect2, varscan2
- CNTNAP2 | c.1158G>T p.V386= | Silent (SNP) | VAF 19/393 reads (5%) | catalogued as COSV62170095, COSV62264276; called by muse, mutect2
- CYBB | c.213C>G p.V71= | Silent (SNP) | VAF 42/531 reads (8%) | called by muse, mutect2
- DCSTAMP | c.132G>T p.V44= | Silent (SNP) | VAF 46/1167 reads (4%) | called by muse, mutect2
- DNAJC22 | c.885G>C p.R295= | Silent (SNP) | VAF 52/346 reads (15%) | called by muse, mutect2, varscan2
- ELMO2 | c.171T>C p.P57= | Silent (SNP) | VAF 41/338 reads (12%) | called by muse, mutect2, varscan2
- EPAS1 | c.1053C>T p.D351= | Silent (SNP) | VAF 37/502 reads (7%) | catalogued as rs757088702, COSV55385125; called by muse, mutect2
- ESR1 | c.549C>T p.R183= | Silent (SNP) | VAF 36/430 reads (8%) | called by muse, mutect2
- EXT2 | c.1338C>T p.L446= (on ENST00000343631; = p.L479= on NM_000401.3) | Silent (SNP) | VAF 43/362 reads (12%) | called by muse, mutect2, varscan2
- FAM205A | c.3504T>C p.G1168= | Silent (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- FSIP2 | c.6300T>C p.D2100= | Silent (SNP) | VAF 11/373 reads (3%) | called by muse, mutect2
- FSIP2 | c.15543T>C p.S5181= | Silent (SNP) | VAF 16/173 reads (9%) | called by muse, mutect2
- GARS1 | c.1200G>T p.V400= | Silent (SNP) | VAF 121/822 reads (15%) | called by muse, mutect2, varscan2
- GFPT1 | c.1617G>C p.L539= (on ENST00000357308 / NM_001244710.2; = p.L521= on NM_002056.4) | Silent (SNP) | VAF 31/575 reads (5%) | called by muse, mutect2
- HAP1 | c.117G>A p.A39= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as rs890928392, COSV57879078; called by muse, mutect2
- HERC2 | c.1302A>G p.K434= | Silent (SNP) | VAF 18/315 reads (6%) | called by muse, mutect2
- HIVEP1 | c.3192G>C p.L1064= | Silent (SNP) | VAF 28/179 reads (16%) | called by muse, mutect2, varscan2
- MYL12A | c.207A>G p.L69= | Silent (SNP) | VAF 83/510 reads (16%) | called by muse, mutect2, varscan2
- NHSL1 | c.4503C>T p.Y1501= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- NIBAN2 | c.1095C>T p.F365= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- NPAS3 | c.1779C>T p.A593= (on ENST00000356141 / NM_001164749.2; = p.A561= on NM_022123.3) | Silent (SNP) | VAF 9/188 reads (5%) | catalogued as rs1039680597; called by muse, mutect2
- OR2H1 | c.138G>T p.L46= | Silent (SNP) | VAF 70/614 reads (11%) | called by muse, mutect2, varscan2
- OR4C12 | c.690G>T p.G230= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as COSV100078379; called by muse, mutect2
- OR51V1 | c.585C>A p.I195= | Silent (SNP) | VAF 34/259 reads (13%) | catalogued as COSV100343297; called by muse, varscan2
- PCDH11X | c.2715A>G p.L905= | Silent (SNP) | VAF 85/522 reads (16%) | called by muse, mutect2, varscan2
- PCSK2 | c.1008C>T p.N336= | Silent (SNP) | VAF 41/488 reads (8%) | catalogued as rs762559214, COSV52727055; called by muse, mutect2
- PDZRN4 | c.2298C>T p.L766= (on ENST00000402685 / NM_001164595.2; = p.L508= on NM_013377.4) | Silent (SNP) | VAF 28/390 reads (7%) | called by muse, mutect2
- PRG3 | c.201T>C p.S67= | Silent (SNP) | VAF 23/334 reads (7%) | catalogued as rs1365882013; called by muse, mutect2
- RGS6 | c.531A>G p.Q177= | Silent (SNP) | VAF 40/287 reads (14%) | called by muse, mutect2, varscan2
- SPINDOC | c.45G>T p.V15= | Silent (SNP) | VAF 7/142 reads (5%) | called by muse, mutect2
- SSR4 | c.162C>T p.S54= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- SUSD5 | c.1056C>A p.G352= | Silent (SNP) | VAF 34/322 reads (11%) | called by muse, mutect2
- TECPR2 | c.822G>A p.L274= | Silent (SNP) | VAF 19/137 reads (14%) | called by muse, mutect2, varscan2
- VAT1 | c.1173G>A p.K391= | Silent (SNP) | VAF 32/178 reads (18%) | called by muse, varscan2
- VSX1 | c.612C>T p.P204= | Silent (SNP) | VAF 58/491 reads (12%) | catalogued as rs200369946; called by muse, mutect2, varscan2
- WNT5B | c.837C>A p.V279= | Silent (SNP) | VAF 17/126 reads (13%) | called by muse, mutect2, varscan2
- XPO4 | c.1386A>G p.E462= | Silent (SNP) | VAF 37/302 reads (12%) | called by muse, mutect2, varscan2
- ZNFX1 | c.4998C>T p.A1666= | Silent (SNP) | VAF 14/289 reads (5%) | called by muse, mutect2
- ANXA2 | c.148+7867G>C | Intron (SNP) | VAF 57/366 reads (16%) | called by muse, mutect2, varscan2
- CHRNB1 | c.244-22C>G | Intron (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- CSTB | c.-1G>C | 5'UTR (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- GABRA3 | c.-26-27638T>C | Intron (SNP) | VAF 54/248 reads (22%) | called by muse, mutect2, varscan2
- HSPA7 | n.574G>A | RNA (SNP) | VAF 17/142 reads (12%) | catalogued as rs1299098760; called by muse, mutect2, varscan2
- LIF | c.-3A>G | 5'UTR (SNP) | VAF 45/311 reads (14%) | called by muse, mutect2, varscan2
- MIEF1 | c.*949A>T | 3'UTR (SNP) | VAF 51/291 reads (18%) | called by muse, mutect2, varscan2
- MIR205 | n.94G>C | RNA (SNP) | VAF 37/728 reads (5%) | called by muse, mutect2
- MRTFA | c.601+163C>G | Intron (SNP) | VAF 12/62 reads (19%) | called by mutect2, varscan2
- NUDCD3 | c.786+1734C>G | Intron (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- OR7D1P | n.437T>C | RNA (SNP) | VAF 24/526 reads (5%) | called by muse, mutect2
- OTUB1 | c.120+19C>T | Intron (SNP) | VAF 8/84 reads (10%) | catalogued as rs968429585; called by mutect2, varscan2
- PATE1 | c.-21C>A | 5'UTR (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- PDGFA | chr7:520016 G>T | 5'Flank (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- PKIA | c.*9T>C | 3'UTR (SNP) | VAF 18/398 reads (5%) | called by muse, mutect2
- PMPCA | c.1408+30C>T | Intron (SNP) | VAF 3/46 reads (7%) | catalogued as rs1354700769; called by muse, mutect2
- PPP2R2B | c.74+1038T>A | Intron (SNP) | VAF 30/327 reads (9%) | called by muse, mutect2, varscan2
- RGS6 | c.1368+3788G>C | Intron (SNP) | VAF 18/400 reads (5%) | called by muse, mutect2
- RNU7-115P | chr17:64822380 C>A | 3'Flank (SNP) | VAF 101/485 reads (21%) | called by muse, mutect2, varscan2
- SLC12A1 | c.-312G>A | 5'UTR (SNP) | VAF 20/302 reads (7%) | catalogued as rs1208428504; called by muse, mutect2
- SLC43A3 | c.770-288A>T | Intron (SNP) | VAF 16/161 reads (10%) | called by muse, mutect2
- SUGT1P4-STRA6LP | n.828C>T | RNA (SNP) | VAF 28/292 reads (10%) | catalogued as rs1392712109; called by muse, mutect2, varscan2
- TERF1 | c.320-983A>C | Intron (SNP) | VAF 24/315 reads (8%) | called by muse, mutect2
- TTC3P1 | n.5167C>G | RNA (SNP) | VAF 11/168 reads (7%) | called by muse, mutect2
- USH1C | c.1285-7612T>A | Intron (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2
